Gene-level copy-number profile of tumor specimen C3N-00169-03 from CPTAC case C3N-00169, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.5 years (21,005 days).
Specimen C3N-00169-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0dd286cb-2a80-4148-b9cd-81d4f613612d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00169-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/3e7e88d4-e3b1-4a21-98c9-daa21cd56323

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 18; copy number 2: 20,168; copy number 3: 9,541; copy number 4: 26,598; copy number 5: 235; copy number 6: 496; copy number 7: 618; copy number 8: 82; copy number 9: 230; copy number 10: 308; copy number 11: 43; copy number 12: 27; copy number 13: 19.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 627 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,719,471–151,348,027, 230 genes, copy number 9 (broad region; genes not listed).
- chr1:151,870,866–155,563,162, 208 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr5:33,424,025–44,808,777, 187 genes, copy number 10–13 (broad region; genes not listed).
- chr20:34,833,575–34,872,856, 2 genes, copy number 11 (within-gene range 4–11): HMGB3P1, GGT7.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
